Somatic mutation profile of tumor specimen TCGA-CQ-A4CD-01A (aliquot TCGA-CQ-A4CD-01A-21D-A25D-08) from TCGA case TCGA-CQ-A4CD, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Mandible; AJCC pathologic stage: Stage IVA; Tumor grade: G3; Age at diagnosis: 69.8 years (25,497 days).
Specimen TCGA-CQ-A4CD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 97b08570-0e1a-4ca9-8d3f-457758634b66.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CQ-A4CD-10A (Blood Derived Normal), aliquot TCGA-CQ-A4CD-10A-01D-A25E-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/aa24d453-dcd3-4cc5-8f5c-abf1d032dd8e

The open-access MAF lists 163 somatic variants for this specimen: 134 protein-altering or splice-affecting, 26 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 111, Silent 26, Nonsense Mutation 15, Splice Site 4, Frame Shift Del 2, Frame Shift Ins 2, RNA 1, 5'Flank 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.205G>T p.E69* | Nonsense Mutation (SNP) | VAF 6/14 reads (43%) | catalogued as rs121913383, COSV58683264, COSV58724303, COSV58727969; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FLG | c.8117C>G p.S2706* | Nonsense Mutation (SNP) | VAF 8/52 reads (15%) | catalogued as rs542799026, CM108254; ClinVar: pathogenic; called by mutect2, varscan2
- TP53 | c.406C>G p.Q136E | Missense Mutation (SNP) | VAF 12/58 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs1555526268, CM971503, COSV52676850, COSV52715987, COSV52740951; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- WT1 | c.1069C>T p.R357* | Nonsense Mutation (SNP) | VAF 14/44 reads (32%) | catalogued as rs1423753702, CM971594, COSV60067818, COSV60068249, COSV60071382, COSV60073329, COSV60074859, COSV60075137; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AATK | c.884G>A p.R295H (on ENST00000326724 / NM_001080395.3; = p.R192H on NM_004920.2) | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100452718; called by muse, mutect2, varscan2
- ABHD8 | c.1015C>T p.R339W | Missense Mutation (SNP) | VAF 39/140 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99917181; called by muse, mutect2, varscan2
- AFTPH | c.1454A>G p.N485S | Missense Mutation (SNP) | VAF 36/115 reads (31%) | SIFT tolerated (0.66); PolyPhen benign (0.007); catalogued as rs1477454196, COSV99480451; called by muse, mutect2, varscan2
- AMER2 | c.1726G>A p.E576K | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.79); catalogued as rs779469585, COSV100766183; called by muse, mutect2, varscan2
- AMOTL2 | c.634C>G p.Q212E | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99998098; called by muse, mutect2, varscan2
- APBB1IP | c.1444G>C p.E482Q | Missense Mutation (SNP) | VAF 36/145 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as COSV100882003; called by muse, mutect2, varscan2
- ARL5A | c.200T>C p.I67T | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.754); catalogued as rs1268776848, COSV99706575; called by muse, mutect2, varscan2
- BRD8 | c.2207T>G p.V736G (on ENST00000254900 / NM_139199.2; = p.V809G on NM_006696.4) | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99136762; called by muse, mutect2, varscan2
- BSN | c.3586G>A p.E1196K | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.081); catalogued as COSV99607810; called by muse, mutect2, varscan2
- C16orf72 | c.643C>T p.H215Y | Missense Mutation (SNP) | VAF 25/127 reads (20%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.528); catalogued as COSV100589002; called by muse, mutect2, varscan2
- C1QTNF7 | c.170G>A p.R57H | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs137951137, COSV99765094; called by muse, mutect2, varscan2
- C1S | c.664G>T p.D222Y | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.309); catalogued as COSV61072896; called by muse, mutect2, varscan2
- C7orf25 | c.671G>C p.R224T | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT tolerated (0.52); PolyPhen benign (0.022); catalogued as COSV63274516; called by muse, mutect2, varscan2
- CA3 | c.214G>C p.D72H | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99570616; called by muse, mutect2, varscan2
- CCNT1 | c.431T>C p.L144S | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99980633; called by muse, mutect2
- CDC42BPG | c.4207C>T p.R1403C | Missense Mutation (SNP) | VAF 24/160 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs770058353, COSV61345764; called by muse, mutect2, varscan2
- CDCA5 | c.44C>G p.S15C | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.879); catalogued as COSV99297741; called by muse, mutect2, varscan2
- CDH18 | c.1069C>T p.R357C | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs759919566, COSV56916333; called by muse, mutect2, varscan2
- CDH9 | c.983T>A p.I328N | Missense Mutation (SNP) | VAF 68/195 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); catalogued as COSV50259845; called by muse, mutect2, varscan2
- CDKN3 | c.145C>A p.P49T | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53593015, COSV99369824; called by muse, mutect2, varscan2
- CENPF | c.380G>C p.R127T | Missense Mutation (SNP) | VAF 49/113 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100871609, COSV65276845; called by muse, mutect2, varscan2
- CHP2 | c.493G>A p.D165N | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV55650221; called by muse, mutect2, varscan2
- COL22A1 | c.1793G>A p.R598Q | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs201581690, COSV100277314; called by muse, mutect2, varscan2
- COL4A4 | c.1112A>G p.D371G | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1275375343, COSV100306505; called by muse, mutect2, varscan2
- COL4A5 | c.1060A>G p.T354A | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV100087147; called by muse, mutect2, varscan2
- COQ5 | c.891C>G p.F297L | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.533); catalogued as COSV99942232; called by muse, mutect2, varscan2
- CRX | c.232C>G p.L78V | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV55758178, COSV55760186; called by muse, mutect2, varscan2
- CTSS | c.737G>T p.G246V | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100934932; called by muse, mutect2, varscan2
- DCAF12L2 | c.1040G>C p.R347P | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.511); catalogued as rs985362831, COSV100758520, COSV63581089, COSV63583859; called by muse, mutect2, varscan2
- DEF8 | c.166G>A p.E56K | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as rs1232298111, COSV99240370; called by muse, mutect2, varscan2
- DEPDC1 | c.536G>C p.R179T | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.632); catalogued as COSV100920247; called by muse, mutect2, varscan2
- DIP2B | c.1037G>A p.W346* | Nonsense Mutation (SNP) | VAF 16/47 reads (34%) | catalogued as COSV99998208; called by muse, mutect2, varscan2
- DOCK7 | c.2683C>T p.R895* | Nonsense Mutation (SNP) | VAF 13/50 reads (26%) | catalogued as rs1450310137, COSV99223687; called by muse, mutect2, varscan2
- DSC2 | c.321G>C p.K107N | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV51864655, COSV99199563; called by muse, mutect2, varscan2
- DYNC1H1 | c.8662G>C p.E2888Q | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT tolerated (0.85); PolyPhen benign (0.017); catalogued as COSV100794671; called by muse, mutect2, varscan2
- EPS15 | c.1974C>G p.F658L | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100869475; called by muse, mutect2, varscan2
- F13A1 | c.839G>T p.W280L | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53561579, COSV99342610; called by muse, mutect2, varscan2
- FARS2 | c.1281G>C p.Q427H | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.834); catalogued as COSV99212949; called by muse, mutect2, varscan2
- FICD | c.749G>A p.R250H | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs776345995, COSV57207160; called by muse, mutect2, varscan2
- FN1 | c.2548G>A p.E850K | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100116648; called by muse, mutect2, varscan2
- FUCA2 | c.1330G>T p.E444* | Nonsense Mutation (SNP) | VAF 13/45 reads (29%) | catalogued as rs1562662531, COSV99136006; called by muse, mutect2, varscan2
- FYN | c.763G>A p.D255N | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.065); catalogued as COSV99991424; called by muse, mutect2, varscan2
- FZD6 | c.1354G>C p.D452H | Missense Mutation (SNP) | VAF 35/217 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as COSV100708340; called by muse, mutect2, varscan2
- GGT1 | c.1519C>T p.Q507* | Nonsense Mutation (SNP) | VAF 19/110 reads (17%) | catalogued as COSV99958717; called by muse, mutect2, varscan2
- GIGYF2 | c.3376C>T p.Q1126* | Nonsense Mutation (SNP) | VAF 21/64 reads (33%) | catalogued as COSV101004166, COSV101004184; called by muse, mutect2, varscan2
- GPR149 | c.1876G>C p.D626H | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV101078256, COSV67669128; called by muse, mutect2, varscan2
- GRIK2 | c.473G>A p.R158H | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.42); PolyPhen benign (0.015); catalogued as rs376865962; called by muse, mutect2, varscan2
- HERC1 | c.488G>T p.R163L | Missense Mutation (SNP) | VAF 49/209 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as rs375843350, COSV71248119; called by muse, mutect2, varscan2
- HYPK | c.266T>A p.L89Q | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV99979771; called by muse, mutect2
- ICA1L | c.242C>G p.S81* | Nonsense Mutation (SNP) | VAF 15/43 reads (35%) | catalogued as COSV100841707; called by muse, mutect2, varscan2
- IGF1R | c.1115C>T p.S372L | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.052); catalogued as rs147236845; called by muse, mutect2, varscan2
- IKZF3 | c.1502G>C p.R501T | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53108996; called by muse, mutect2, varscan2
- IQCK | c.251C>A p.A84E | Missense Mutation (SNP) | VAF 26/111 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.148); catalogued as rs781672599, COSV100244378, COSV100244657; called by muse, mutect2, varscan2
- KIAA1109 | c.675C>G p.I225M | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as COSV99151042; called by muse, mutect2, varscan2
- KRT82 | c.607G>A p.G203S | Missense Mutation (SNP) | VAF 30/140 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.04); catalogued as rs1213172427, COSV99233469; called by muse, mutect2, varscan2
- LARS1 | c.1494G>C p.M498I (on ENST00000394434 / NM_020117.11; = p.M471I on NM_016460.3) | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.309); catalogued as COSV99198525; called by muse, mutect2, varscan2
- LIMS2 | c.983C>T p.S328F (on ENST00000355119 / NM_001161403.3; = p.S352F on NM_017980.4) | Missense Mutation (SNP) | VAF 29/122 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.205); catalogued as rs749084508, COSV100264392; called by muse, mutect2, varscan2
- LIPI | c.755G>C p.G252A | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100753563; called by muse, mutect2, varscan2
- LRRC39 | c.69G>T p.K23N | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.024); catalogued as COSV100734416; called by muse, mutect2, varscan2
- LYST | c.6709C>T p.Q2237* | Nonsense Mutation (SNP) | VAF 40/93 reads (43%) | catalogued as COSV67705420; called by muse, mutect2, varscan2
- MCU | c.685G>C p.E229Q | Missense Mutation (SNP) | VAF 38/179 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.636); catalogued as COSV100849120; called by muse, mutect2, varscan2
- MMP10 | c.623G>A p.G208D | Missense Mutation (SNP) | VAF 19/423 reads (4%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as rs1385347247, COSV99666471; called by muse, mutect2
- MPDZ | c.5190G>C p.K1730N | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100056451, COSV59919457; called by muse, mutect2, varscan2
- MSL2 | c.271G>C p.E91Q | Missense Mutation (SNP) | VAF 39/161 reads (24%) | SIFT tolerated (0.37); PolyPhen benign (0.006); catalogued as COSV99386744; called by muse, mutect2, varscan2
- MUC16 | c.38916C>G p.F12972L | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.071); catalogued as COSV101199103; called by muse, mutect2, varscan2
- MUC5B | c.8696C>T p.S2899F | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.314); catalogued as COSV101500181; called by muse, mutect2, varscan2
- NCOR1 | c.3242C>T p.P1081L | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.57); catalogued as rs1237541182, COSV51994234; called by muse, mutect2, varscan2
- NFKB2 | c.2203G>A p.D735N | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as COSV50042425; called by muse, mutect2, varscan2
- NPBWR2 | c.844G>A p.V282M | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs751123142, COSV63900540; called by muse, mutect2, varscan2
- PCBP2 | c.376-1G>A p.X126_splice | Splice Site (SNP) | VAF 17/59 reads (29%) | catalogued as COSV100827422, COSV63729265; called by muse, mutect2, varscan2
- PCDH9 | c.1904G>C p.R635T | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100119457; called by muse, mutect2, varscan2
- PDE4A | c.1205G>A p.R402Q (on ENST00000380702 / NM_001111307.2; = p.R163Q on NM_006202.3) | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.687); catalogued as rs201529049, COSV99534592; called by mutect2, varscan2
- PIGO | c.1252G>C p.E418Q | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.091); catalogued as COSV53055132, COSV99956540; called by muse, mutect2, varscan2
- PIP5K1B | c.206G>T p.G69V | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.611); catalogued as COSV99598430; called by muse, mutect2, varscan2
- PKHD1L1 | c.5302G>A p.E1768K | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT tolerated (0.52); PolyPhen benign (0.007); catalogued as COSV101005798; called by muse, mutect2, varscan2
- PSG3 | c.925C>G p.Q309E | Missense Mutation (SNP) | VAF 46/189 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs1181270467, COSV100548811; called by muse, mutect2, varscan2
- PTPRK | c.2179C>T p.R727C | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as rs377279284; called by muse, mutect2, varscan2
- PXDNL | c.859G>A p.D287N | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.893); catalogued as COSV62487821; called by muse, mutect2, varscan2
- QDPR | c.475C>G p.Q159E | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.585); catalogued as COSV55552071, COSV99845759; called by muse, mutect2, varscan2
- RAB3GAP1 | c.1237T>C p.F413L | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.079); catalogued as COSV99920868; called by muse, mutect2
- RB1CC1 | c.2828C>T p.S943F | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.054); catalogued as COSV99209815; called by muse, mutect2, varscan2
- RGS22 | c.1081C>T p.H361Y | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs748025858, COSV62659119; called by muse, mutect2, varscan2
- RNF157 | c.1327G>A p.V443M | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.048); catalogued as rs201495655, COSV53942053; called by muse, mutect2, varscan2
- RNF213 | c.7498G>C p.E2500Q | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100300102, COSV60400915; called by muse, mutect2, varscan2
- ROS1 | c.3517C>G p.Q1173E | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated (0.43); PolyPhen benign (0.027); catalogued as COSV100876779; called by muse, mutect2, varscan2
- RYR1 | c.9466G>A p.V3156I | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.095); catalogued as rs150230127; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SASH1 | c.3574C>G p.P1192A | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100821067; called by muse, mutect2, varscan2
- SH2D3C | c.38-1G>C p.X13_splice | Splice Site (SNP) | VAF 7/48 reads (15%) | catalogued as COSV99043018; called by muse, mutect2, varscan2
- SIN3B | c.1833C>G p.F611L | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV56133445, COSV56137285; called by muse, mutect2, varscan2
- SLC15A2 | c.1147G>A p.G383S | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99815320; called by muse, mutect2, varscan2
- SLC18A2 | c.874C>T p.P292S | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100041473; called by muse, mutect2, varscan2
- SLC9C2 | c.1098A>T p.E366D | Missense Mutation (SNP) | VAF 13/186 reads (7%) | SIFT tolerated (0.42); PolyPhen benign (0.359); catalogued as COSV100876657; called by muse, mutect2
- SLIT1 | c.639C>A p.H213Q | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.539); catalogued as COSV99820959; called by muse, mutect2
- SMC5 | c.1189C>G p.Q397E | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.785); catalogued as COSV100747014; called by muse, mutect2, varscan2
- SORCS3 | c.1955C>T p.P652L | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV100863480, COSV100863517; called by muse, mutect2, varscan2
- SP2 | c.676G>A p.G226R | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.561); catalogued as rs750001387, COSV65063591; called by muse, mutect2, varscan2
- SPATA16 | c.1520C>A p.A507E | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.676); catalogued as COSV100651038; called by muse, mutect2, varscan2
- SPSB3 | c.202G>A p.E68K | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.857); catalogued as rs753479651, COSV51905174; called by muse, mutect2, varscan2
- SPTLC1 | c.494C>G p.S165* | Nonsense Mutation (SNP) | VAF 10/72 reads (14%) | catalogued as COSV99364652; called by muse, mutect2, varscan2
- SRRM2 | c.5334G>C p.R1778S | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.715); catalogued as rs1289628540, COSV100070501; called by muse, mutect2, varscan2
- SRSF12 | c.561G>C p.K187N | Missense Mutation (SNP) | VAF 58/248 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.261); catalogued as COSV101504965; called by muse, mutect2, varscan2
- SSTR1 | c.826G>A p.V276M | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.824); catalogued as rs759519125, COSV57456352; called by muse, mutect2, varscan2
- STAG3 | c.2242C>G p.L748V | Missense Mutation (SNP) | VAF 22/117 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.052); catalogued as rs765579451, COSV100425773; called by muse, mutect2, varscan2
- STK11 | c.298C>T p.Q100* | Nonsense Mutation (SNP) | VAF 21/74 reads (28%) | catalogued as CM991151, COSV58822329, COSV58830813; called by muse, mutect2, varscan2
- SULF1 | c.38T>G p.L13R | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.161); catalogued as COSV99482615; called by muse, mutect2, varscan2
- TAS2R31 | c.332C>T p.A111V | Missense Mutation (SNP) | VAF 12/135 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.4); catalogued as COSV101114483; called by muse, mutect2
- TDRD1 | c.1723G>A p.G575R | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52589603; called by muse, mutect2, varscan2
- TDRD5 | c.1912G>C p.D638H | Missense Mutation (SNP) | VAF 28/148 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99675857; called by muse, mutect2, varscan2
- TENM4 | c.7113T>A p.S2371R | Missense Mutation (SNP) | VAF 15/142 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99572736; called by muse, mutect2, varscan2
- TFDP1 | c.564G>C p.E188D | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.601); catalogued as COSV100945780; called by muse, mutect2, varscan2
- TMCO2 | c.386T>C p.I129T | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV65646969; called by muse, mutect2, varscan2
- TNS2 | c.350+3_350+6del p.X117_splice (on ENST00000314250 / NM_170754.4; = p.X127_splice on NM_015319.2) | Splice Site (DEL) | VAF 9/39 reads (23%) | catalogued as rs1460611163; called by mutect2, pindel, varscan2
- TPX2 | c.863G>T p.R288L | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs746496077, COSV100301609, COSV55919474; called by muse, mutect2, varscan2
- TRDMT1 | c.815C>A p.S272* | Nonsense Mutation (SNP) | VAF 13/67 reads (19%) | catalogued as COSV100003770, COSV100003844; called by muse, mutect2, varscan2
- TRIM14 | c.616G>A p.E206K | Missense Mutation (SNP) | VAF 44/94 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.322); catalogued as COSV100419524; called by muse, mutect2, varscan2
- UGT1A4 | c.758C>G p.S253C | Missense Mutation (SNP) | VAF 46/203 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100530045, COSV59382889; called by muse, mutect2, varscan2
- UPF1 | c.976C>T p.Q326* | Nonsense Mutation (SNP) | VAF 17/74 reads (23%) | catalogued as COSV99439134; called by muse, mutect2, varscan2
- USP4 | c.2717C>G p.S906C | Missense Mutation (SNP) | VAF 39/95 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.071); catalogued as COSV99649166; called by muse, mutect2, varscan2
- VPS13B | c.794C>G p.S265C | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62016330; called by muse, mutect2, varscan2
- WWC3 | c.2662C>T p.R888W | Missense Mutation (SNP) | VAF 50/103 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.171); catalogued as rs371007227, COSV66501956; called by muse, mutect2, varscan2
- ZBTB46 | c.1736G>A p.G579E | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.021); catalogued as COSV99828950; called by muse, mutect2
- ZFC3H1 | c.5276C>A p.S1759* | Nonsense Mutation (SNP) | VAF 24/82 reads (29%) | catalogued as COSV101110421; called by muse, mutect2, varscan2
- ZFP41 | c.575G>A p.R192H | Missense Mutation (SNP) | VAF 41/161 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs774281768, COSV100414631; called by muse, mutect2, varscan2
- ZNF142 | c.224T>A p.I75N | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.833); catalogued as COSV100826579; called by muse, mutect2, varscan2
- ZNF641 | c.301C>G p.L101V | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.333); catalogued as COSV99973432; called by muse, mutect2
- CDK4 | c.207dup p.N70Qfs*15 | Frame Shift Ins (INS) | VAF 24/96 reads (25%) | called by mutect2, pindel, varscan2
- COL4A4 | c.3818-4_3826del p.X1273_splice | Splice Site (DEL) | VAF 11/40 reads (28%) | called by mutect2, pindel, varscan2
- FAT1 | c.2330dup p.L777Ffs*5 | Frame Shift Ins (INS) | VAF 27/107 reads (25%) | called by mutect2, pindel, varscan2
- OLFM3 | c.279del p.Q94Rfs*10 (on ENST00000338858 / NM_001288821.1; = p.Q74Rfs*10 on NM_058170.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 17/83 reads (20%) | called by mutect2, pindel, varscan2
- TP53 | c.1147_1150del p.L383Cfs*38 | Frame Shift Del (DEL) | VAF 18/127 reads (14%) | called by mutect2, pindel, varscan2
- AURKAIP1 | c.357C>T p.V119= | Silent (SNP) | VAF 29/89 reads (33%) | catalogued as COSV100408638; called by muse, mutect2, varscan2
- BSN | c.8712G>A p.E2904= | Silent (SNP) | VAF 23/67 reads (34%) | catalogued as rs945245814, COSV56520372; called by muse, mutect2, varscan2
- C9orf131 | c.54C>G p.L18= | Silent (SNP) | VAF 6/53 reads (11%) | catalogued as COSV100397993; called by muse, mutect2, varscan2
- CAPN6 | c.1272G>A p.E424= | Silent (SNP) | VAF 31/77 reads (40%) | catalogued as COSV100136787; called by muse, mutect2, varscan2
- CCNL2 | c.207C>T p.L69= | Silent (SNP) | VAF 11/43 reads (26%) | catalogued as rs758806715, COSV100784954; called by muse, mutect2, varscan2
- CDKN3 | c.144T>A p.L48= | Silent (SNP) | VAF 19/69 reads (28%) | catalogued as COSV99369823; called by muse, mutect2, varscan2
- CHAC1 | c.228G>A p.K76= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as COSV101471067; called by muse, mutect2, varscan2
- DYNC2H1 | c.901C>T p.L301= | Silent (SNP) | VAF 14/324 reads (4%) | catalogued as COSV100518066; called by muse, mutect2
- GUCY2D | c.1761C>G p.L587= | Silent (SNP) | VAF 12/49 reads (24%) | catalogued as COSV99643857; called by muse, mutect2, varscan2
- H2BC18 | c.222C>T p.I74= | Silent (SNP) | VAF 29/173 reads (17%) | catalogued as rs782575950, COSV100516145, COSV58944587; called by muse, mutect2, varscan2
- HERC2 | c.4833T>C p.S1611= | Silent (SNP) | VAF 30/121 reads (25%) | catalogued as rs780063697, COSV99872111; called by muse, mutect2, varscan2
- IL34 | c.634C>T p.L212= | Silent (SNP) | VAF 31/104 reads (30%) | catalogued as rs1490697910, COSV99851773; called by muse, mutect2, varscan2
- MORN3 | c.231C>T p.L77= | Silent (SNP) | VAF 24/72 reads (33%) | catalogued as COSV100804461; called by muse, mutect2, varscan2
- OR10H5 | c.549T>C p.P183= | Silent (SNP) | VAF 8/88 reads (9%) | catalogued as COSV100454668; called by muse, mutect2
- OR4P4 | c.645T>C p.S215= | Silent (SNP) | VAF 18/71 reads (25%) | catalogued as COSV100111653; called by muse, mutect2, varscan2
- ORC1 | c.2205C>T p.F735= | Silent (SNP) | VAF 15/67 reads (22%) | catalogued as COSV100856634; called by muse, mutect2, varscan2
- PTK7 | c.363C>T p.I121= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as COSV100030019; called by muse, mutect2, varscan2
- RESF1 | c.366A>G p.S122= | Silent (SNP) | VAF 18/66 reads (27%) | catalogued as COSV100440240; called by muse, mutect2, varscan2
- SLC1A5 | c.1581C>T p.P527= | Silent (SNP) | VAF 39/188 reads (21%) | catalogued as rs372990738; called by muse, mutect2, varscan2
- TMED2 | c.60C>G p.G20= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as COSV99147764; called by muse, mutect2, varscan2
- TNFRSF1A | c.1275C>G p.L425= | Silent (SNP) | VAF 6/11 reads (55%) | catalogued as COSV50608353, COSV99164132; called by muse, mutect2, varscan2
- TNFSF11 | c.765G>C p.L255= | Silent (SNP) | VAF 33/91 reads (36%) | catalogued as rs999414831, COSV53480131, COSV99520394; called by muse, mutect2, varscan2
- UHRF1 | c.1530C>G p.L510= (on ENST00000612630 / NM_001290050.1; = p.L523= on NM_013282.4) | Silent (SNP) | VAF 17/42 reads (40%) | catalogued as rs1418841775, COSV99503391; called by muse, mutect2, varscan2
- UNC13B | c.3540G>A p.L1180= | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as COSV101036449, COSV65937172; called by muse, mutect2, varscan2
- ZNF142 | c.225C>T p.I75= | Silent (SNP) | VAF 8/52 reads (15%) | catalogued as COSV100826578; called by muse, mutect2, varscan2
- ZNF572 | c.87A>T p.T29= | Silent (SNP) | VAF 12/87 reads (14%) | catalogued as COSV60002156; called by muse, mutect2, varscan2
- FAM183BP | n.1127C>T | RNA (SNP) | VAF 28/80 reads (35%) | catalogued as rs984104891; called by muse, mutect2, varscan2
- RNU7-174P | chr8:80559230 C>G | 5'Flank (SNP) | VAF 17/86 reads (20%) | called by muse, mutect2, varscan2
- SLC25A25 | c.262-9137G>C | Intron (SNP) | VAF 28/195 reads (14%) | catalogued as COSV100895503; called by muse, mutect2, varscan2
